Somatic mutation profile of tumor specimen 0DN1DF from CCDI case PBCBCI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.7 years (6,825 days).
Specimen 0DN1DF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2af1cd6e-a0f4-4e8c-86d2-173e91d06e31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37b7d0e5-1425-46ba-b58e-d146e00a2585

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Intron 3, Nonsense Mutation 3, 3'UTR 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRCAP | c.7330C>T p.R2444* | Nonsense Mutation (SNP) | VAF 481/1263 reads (38%) | catalogued as rs199469464, CM121172, COSV52667926; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 91/807 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs141186395; called by muse, mutect2, varscan2
- CFAP61 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 491/1919 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs375676702; called by muse, mutect2, varscan2
- FAT1 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 448/1867 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs772257246, COSV71673702; called by muse, mutect2, varscan2
- FCGRT | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 351/1167 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs756120751; called by muse, mutect2, varscan2
- FOLH1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 720/1914 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs757958518, COSV57054870; called by muse, mutect2, varscan2
- FSHR | c.1969G>C p.E657Q | Missense Mutation (SNP) | VAF 72/1924 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.942); catalogued as COSV58617229, COSV58622859; called by muse, mutect2
- GTF3C1 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 34/1238 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs950416834; called by muse, mutect2
- KCNG2 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 128/250 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs748144545; called by muse, mutect2, varscan2
- MICAL2 | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 199/1762 reads (11%) | catalogued as rs750306542, COSV56285623; called by muse, mutect2, varscan2
- RTP5 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 348/776 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.445); catalogued as rs373858877; called by muse, mutect2, varscan2
- SETD6 | c.1174G>C p.D392H (on ENST00000219315 / NM_001160305.4; = p.D368H on NM_024860.3) | Missense Mutation (SNP) | VAF 697/1856 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs775653104; called by muse, mutect2, varscan2
- SLC2A5 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 44/1670 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1165457693, COSV66236562; called by muse, mutect2
- ACTC1 | c.313A>T p.T105S | Missense Mutation (SNP) | VAF 603/1427 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- AHNAK | c.13034T>C p.I4345T | Missense Mutation (SNP) | VAF 482/1734 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BAG2 | c.634T>C p.*212Qext*21 | Nonstop Mutation (SNP) | VAF 183/1680 reads (11%) | called by muse, mutect2, varscan2
- ENTPD6 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 610/2314 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.18); called by muse, mutect2
- FZD2 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 373/1643 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- HBP1 | c.765+2T>C p.X255_splice | Splice Site (SNP) | VAF 494/1872 reads (26%) | called by muse, mutect2, varscan2
- IQCE | c.1441G>C p.A481P | Missense Mutation (SNP) | VAF 167/799 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA2026 | c.4228A>G p.T1410A | Missense Mutation (SNP) | VAF 211/2048 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KMT2C | c.13849G>A p.E4617K | Missense Mutation (SNP) | VAF 615/1632 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2C | c.5859T>A p.C1953* | Nonsense Mutation (SNP) | VAF 867/2317 reads (37%) | called by muse, mutect2, varscan2
- OR52E5 | c.249G>C p.M83I | Missense Mutation (SNP) | VAF 675/2426 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRDM9 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 809/2116 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SLC28A1 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 470/1218 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D32 | c.2338G>T p.D780Y | Missense Mutation (SNP) | VAF 305/1209 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- TSKS | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 500/1738 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- USB1 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 273/2094 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- XRCC5 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 510/1833 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FCN2 | c.348C>T p.S116= | Silent (SNP) | VAF 186/1683 reads (11%) | catalogued as rs748093561, COSV52478781; called by muse, mutect2, varscan2
- GPC2 | c.990C>T p.Y330= | Silent (SNP) | VAF 194/1920 reads (10%) | catalogued as rs1436622911; called by muse, mutect2, varscan2
- KNDC1 | c.498G>A p.P166= | Silent (SNP) | VAF 237/855 reads (28%) | catalogued as rs373692082; called by muse, mutect2
- LRP3 | c.1269C>T p.C423= | Silent (SNP) | VAF 335/773 reads (43%) | catalogued as rs777704008, COSV53504781; called by muse, mutect2
- OGN | c.879G>A p.P293= | Silent (SNP) | VAF 507/1240 reads (41%) | catalogued as rs201234878, COSV52760338; called by muse, mutect2, varscan2
- ZBTB26 | c.909C>T p.C303= | Silent (SNP) | VAF 472/1806 reads (26%) | catalogued as rs748698493; called by muse, mutect2, varscan2
- DDX60 | c.*63G>T | 3'UTR (SNP) | VAF 155/605 reads (26%) | catalogued as rs1321275031; called by muse, mutect2, varscan2
- SUPT5H | c.320-96G>T | Intron (SNP) | VAF 36/102 reads (35%) | called by mutect2, varscan2
- SYTL1 | c.1006-12T>G | Intron (SNP) | VAF 163/736 reads (22%) | called by muse, mutect2, varscan2
- TNPO2 | c.1864-13C>T | Intron (SNP) | VAF 193/1745 reads (11%) | called by muse, mutect2, varscan2
